Gene-level copy-number profile of tumor specimen TCGA-29-1763-01A from TCGA case TCGA-29-1763, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 43.9 years (16,021 days).
Specimen TCGA-29-1763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8a64e2fc-7ca4-47da-9985-c2a06052518f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1763-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d051cb03-28e3-4ce1-b0ee-346b3f510a14

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 168; copy number 2: 30,086; copy number 3: 10,306; copy number 4: 13,620; copy number 5: 3,560; copy number 6: 1,817; copy number 7: 107; copy number 8: 151.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1763-01A-02D-0559-01): tumor purity 0.74, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,635 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,066,640–64,267,368, 4 genes, copy number 6 (within-gene range 4–6): Y_RNA, ROR1-AS1, AL445205.1, UBE2U.
- chr2:4,514,204–33,599,382, 504 genes, copy number 5 (broad region; genes not listed).
- chr2:33,602,041–33,602,286, 1 gene, copy number 5: ATP6V0E1P3.
- chr2:182,140,036–242,160,153, 1,087 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr3:167,683,298–175,810,548, 111 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr3:175,059,361–189,325,304, 284 genes, copy number 6 (broad region; genes not listed).
- chr4:118,460,224–164,620,837, 593 genes, copy number 6 (broad region; genes not listed).
- chr5:169,552,449–179,515,579, 251 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:135,662,496–135,693,418, 1 gene, copy number 5 (within-gene range 2–5): STMP1.
- chr7:135,681,237–159,233,377, 570 genes, copy number 5 (broad region; genes not listed).
- chr8:56,917,084–77,014,028, 302 genes, copy number 5 (broad region; genes not listed).
- chr8:101,177,878–101,492,499, 14 genes, copy number 5: ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr9:14,475–34,922,921, 515 genes, copy number 5–8 (broad region; genes not listed).
- chr10:34,663,859–42,367,974, 93 genes, copy number 5–6 (broad region; genes not listed).
- chr11:94,415,570–135,075,908, 814 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:28,790,812–41,096,195, 491 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 168. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
